Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAGW, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAGW-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Right orchidectomy; nonseminoma (YST 100%); tumor diameter 4 + 2 cm; tumor confined to testis; no angio-invasion; no invasion of rete testis.

Date of procurement (= date of orchidectomy):

ICD 0.3

Tumor, yolk sac 9071/3
Site. R Testis NOS 062.9
JCD 3/7/14

pathologist

professor of pathology

Criteria	W 1/18/14	Yes	No

Source: NCI Genomic Data Commons file b714510b-404a-436c-956a-0699b233d3ce (TCGA-2G-AAGW.378CE149-CED1-4259-8C11-3D9777807684.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).